Somatic mutation profile of tumor specimen ALCH-B0D6-TTP1-A (aliquot ALCH-B0D6-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0D6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.4 years (27,174 days).
Specimen ALCH-B0D6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d689f1c6-26cc-4b6c-943a-de0db804275c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0D6-NB1-A (Blood Derived Normal), aliquot ALCH-B0D6-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b623ccf-3fe7-49b4-9683-b5ac01483309

The open-access MAF lists 90 somatic variants for this specimen: 59 protein-altering or splice-affecting, 19 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 19, Intron 5, Nonsense Mutation 4, 3'UTR 3, 5'Flank 3, Splice Site 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 51/316 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ANKRD30B | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV100746512; called by muse, mutect2
- AVIL | c.255C>A p.Y85* | Nonsense Mutation (SNP) | VAF 29/341 reads (9%) | catalogued as rs751471028; called by muse, mutect2
- CLK4 | c.1198A>G p.M400V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs891502987; called by muse, mutect2
- COL14A1 | c.2624C>A p.T875K | Missense Mutation (SNP) | VAF 34/434 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV52860232; called by muse, mutect2
- DHRS7B | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs760273532, COSV100683882; called by muse, mutect2, varscan2
- ESPL1 | c.5993A>T p.Y1998F | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99229277; called by muse, mutect2
- EZHIP | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs782401494; called by muse, mutect2
- FSCB | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV100469976; called by muse, mutect2, varscan2
- FSHR | c.878A>G p.N293S | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs200999414; called by muse, mutect2
- GNAO1 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV52613526; called by muse, mutect2, varscan2
- KIAA0232 | c.1516T>G p.L506V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.737); catalogued as COSV56923215; called by muse, mutect2
- MRTFB | c.2873C>T p.P958L (on ENST00000571589 / NM_001365412.2; = p.P908L on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.895); catalogued as COSV57956266; called by muse, mutect2, varscan2
- NLRP3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs141906483; called by muse, mutect2, varscan2
- OR5D18 | c.808C>A p.H270N | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs761012413; called by muse, mutect2
- RTN1 | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs780738582; called by muse, mutect2
- SORBS2 | c.3271A>G p.T1091A (on ENST00000284776 / NM_021069.5; = p.T657A on NM_003603.6) | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1437921067; called by muse, mutect2, varscan2
- TMPRSS2 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs758880900, COSV59823181; called by muse, mutect2, varscan2
- ZNF114 | c.443A>G p.Q148R | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs769370879; called by muse, mutect2, varscan2
- ABTB2 | c.1232del p.L411* | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | called by mutect2, pindel, varscan2
- ADGRL3 | c.2710G>C p.G904R (on ENST00000506720 / NM_001322402.2; = p.G836R on NM_015236.6) | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ANK2 | c.10960G>T p.E3654* | Nonsense Mutation (SNP) | VAF 30/281 reads (11%) | called by muse, mutect2, varscan2
- ATM | c.2228C>T p.S743L | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CBLN2 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.968); called by muse, varscan2
- CCDC42 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CMIP | c.313A>G p.M105V (on ENST00000537098 / NM_198390.2; = p.M11V on NM_030629.3) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- CYLC1 | c.106A>T p.T36S | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DDN | c.1924G>A p.D642N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- DSP | c.4811C>A p.S1604* | Nonsense Mutation (SNP) | VAF 43/232 reads (19%) | called by muse, mutect2, varscan2
- ERP27 | c.539A>G p.H180R | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FGF5 | c.424T>G p.L142V | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.51); called by muse, mutect2
- GABRG3 | c.547C>A p.H183N | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IFIH1 | c.909G>C p.E303D | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- INTS8 | c.779A>T p.Y260F | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2
- LRP2 | c.13621-2A>T p.X4541_splice | Splice Site (SNP) | VAF 46/286 reads (16%) | called by muse, mutect2, varscan2
- MADD | c.3393G>C p.K1131N | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- MUC12 | c.2369C>T p.P790L (on ENST00000379442; = p.P647L on NM_001164462.1) | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.722); called by muse, mutect2
- MUC4 | c.12274G>C p.G4092R | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NALCN | c.3448C>A p.L1150I | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- NHS | c.863C>A p.P288Q | Missense Mutation (SNP) | VAF 57/313 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- OR2T34 | c.606G>C p.M202I | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCARE | c.2006C>G p.S669C | Missense Mutation (SNP) | VAF 37/422 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.33); called by muse, mutect2
- PRKAA1 | c.810C>G p.I270M | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAB32 | c.565G>T p.V189L | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- RPA1 | c.1745A>T p.N582I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPGR | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SEC24C | c.3207C>G p.D1069E | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC24A1 | c.2842A>G p.I948V | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SLFN13 | c.1330A>G p.S444G | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- STARD9 | c.560G>C p.G187A | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAS1R3 | c.1789C>G p.P597A | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TCOF1 | c.4333T>C p.S1445P (on ENST00000377797 / NM_001135243.1; = p.S1368P on NM_000356.4) | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- UNC13C | c.2776G>A p.A926T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWDE | c.2113A>C p.T705P | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- ZBTB16 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 53/282 reads (19%) | called by muse, mutect2, varscan2
- ZFP69B | c.1456C>A p.H486N | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.791); called by muse, mutect2
- ZFYVE26 | c.4193C>T p.S1398F | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZNF41 | c.1957C>T p.H653Y | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ZNF761 | c.545G>T p.C182F | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ADGRB2 | c.405G>A p.A135= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs530877764; called by muse, varscan2
- AJM1 | c.234G>A p.P78= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1212407226; called by muse, mutect2
- CCSAP | c.663G>A p.K221= | Silent (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- CDH12 | c.1146G>A p.P382= | Silent (SNP) | VAF 26/390 reads (7%) | catalogued as rs576847484; called by muse, mutect2
- DDR1 | c.1566T>C p.R522= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs868153822, COSV61323433; called by muse, mutect2
- FER1L5 | c.3327C>A p.I1109= (on ENST00000623019; = p.I1082= on NM_001293083.2) | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs1482662933; called by muse, mutect2, varscan2
- GALNT10 | c.1464C>T p.C488= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as rs141156899; called by muse, mutect2
- KCNN3 | c.1608A>G p.K536= (on ENST00000618040 / NM_001204087.1; = p.K521= on NM_002249.6) | Silent (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- MACO1 | c.1779C>T p.L593= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs778304098; called by muse, mutect2
- MGAM2 | c.1176C>T p.V392= | Silent (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- NCAPD2 | c.2337C>T p.G779= | Silent (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- PLEK | c.82T>C p.L28= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as rs1323282200; called by muse, mutect2
- PLK2 | c.354A>T p.V118= | Silent (SNP) | VAF 46/246 reads (19%) | called by muse, mutect2, varscan2
- PRR11 | c.753A>G p.P251= | Silent (SNP) | VAF 20/135 reads (15%) | called by muse, mutect2, varscan2
- SGIP1 | c.1794C>A p.I598= | Silent (SNP) | VAF 17/149 reads (11%) | called by muse, mutect2, varscan2
- SPHKAP | c.648C>T p.T216= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as rs558528920, COSV100763683; called by muse, mutect2
- SUPT20HL1 | c.702G>A p.P234= | Silent (SNP) | VAF 9/146 reads (6%) | catalogued as rs1293123484; called by muse, mutect2
- SVOPL | c.990C>T p.S330= (on ENST00000419765; = p.S178= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/249 reads (4%) | catalogued as COSV55994202; called by muse, mutect2
- TSC1 | c.1956G>T p.L652= | Silent (SNP) | VAF 17/160 reads (11%) | catalogued as CD972491; called by muse, mutect2, varscan2
- ACOT8 | c.841+169G>C | Intron (SNP) | VAF 11/138 reads (8%) | called by muse, mutect2
- AP000769.3 | chr11:65504093 ins G | 5'Flank (INS) | VAF 21/152 reads (14%) | catalogued as rs753695575; called by mutect2, pindel, varscan2
- EIF5 | c.440-477_440-471delinsT | Intron (DEL) | VAF 18/91 reads (20%) | called by pindel, varscan2*
- GAPVD1 | c.1441+2101_1441+2124del | Intron (DEL) | VAF 9/85 reads (11%) | called by mutect2, pindel
- IL20 | c.*3G>C | 3'UTR (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- JAK3 | c.1786+119G>T | Intron (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2
- KIR3DX1 | n.926C>T | RNA (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99683707; called by muse, varscan2
- MFRP | chr11:119346241 C>A | 5'Flank (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- MYPN | chr10:68106731 A>G | 5'Flank (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- OGG1 | c.*75G>A | 3'UTR (SNP) | VAF 42/231 reads (18%) | called by muse, mutect2, varscan2
- SLC46A3 | c.*521G>C | 3'UTR (SNP) | VAF 20/103 reads (19%) | catalogued as COSV57184490; called by muse, mutect2, varscan2
- TMEM273 | c.43+10011T>C | Intron (SNP) | VAF 11/82 reads (13%) | catalogued as rs1445404559, COSV65154342; called by muse, mutect2, varscan2
